CCDI case PBBKCI — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/5930d5ea-5b4b-4cb6-a2dd-f95b47766787

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Medulloblastoma, NOS: ICD-O-3 morphology code: 9470/3; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 8.6 years (3,145 days).

Biospecimens (3 samples)
- Sample 0DB2AN: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DB2AS: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DB2AX: Tissue type: Tumor; Specimen type: Solid Tissue.
